Somatic mutation profile of tumor specimen TCGA-F2-7273-01A (aliquot TCGA-F2-7273-01A-11D-2154-08) from TCGA case TCGA-F2-7273, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 55.0 years (20,071 days).
Specimen TCGA-F2-7273-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d00ef81-99fe-4c09-a27b-159c1476e65d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F2-7273-10A (Blood Derived Normal), aliquot TCGA-F2-7273-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcc86ec0-11b3-4b90-a20d-4d1d1b96e181

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KAT6B | c.4559G>C p.S1520T | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); catalogued as COSV99769298; called by muse, mutect2
